Somatic mutation profile of tumor specimen BA3368D (aliquot aq-BA3368D) from BEATAML1.0 case 2637, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,991 days).
Specimen BA3368D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84b8633f-7fb7-4b07-b710-0423fe5cff48.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3252D (Solid Tissue Normal), aliquot aq-BA3252D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99023a92-baa5-44a6-b8bb-fb3c49b59a7d

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4111C>T p.Q1371* (on ENST00000378444 / NM_001123385.2; = p.Q1337* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 100/342 reads (29%) | catalogued as rs863224850, COSV60705391; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, varscan2
- NF1 | c.4819del p.Y1607Ifs*17 (on ENST00000358273 / NM_001042492.3; = p.Y1586Ifs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | catalogued as rs876658492, COSV100646964; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EZH2 | c.2002A>T p.N668Y (on ENST00000460911 / NM_001203247.2; = p.N673Y on NM_004456.5) | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1312135, COSV57460964; called by muse, mutect2, varscan2
- PHF6 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 78/250 reads (31%) | catalogued as COSV59700130; called by muse, mutect2, varscan2
- RUNX1 | c.1163_1166dup p.F389Lfs*185 (on ENST00000344691 / NM_001001890.3; = p.F416Lfs*185 on NM_001754.5) | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | catalogued as COSV55874545; called by mutect2, pindel, varscan2
- SLITRK3 | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1468997790; called by muse, mutect2, varscan2
- ZMYM2 | c.2399A>G p.Y800C | Missense Mutation (SNP) | VAF 118/368 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs1371106211; called by muse, mutect2, varscan2
- FLT4 | c.627C>A p.T209= | Silent (SNP) | VAF 66/198 reads (33%) | called by muse, mutect2, varscan2
- NDNF | c.723G>A p.P241= | Silent (SNP) | VAF 130/364 reads (36%) | catalogued as rs375394141; called by muse, varscan2
- PCDHB2 | c.1965G>A p.S655= | Silent (SNP) | VAF 107/336 reads (32%) | catalogued as rs1408646855; called by muse, varscan2
- SGSM1 | c.2544C>T p.D848= (on ENST00000400359 / NM_001039948.4; = p.D787= on NM_133454.3) | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as rs780417324; called by muse, mutect2, varscan2
